Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3952, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3952-01A (Primary Tumor).

This is an invasive, poorly differentiated adenocarcinoma of the colon (according to clinical findings the descending colon) with penetration of all the parietal layers and vascular infiltrates (pT3, L1, V1) with six lymph node metastases (6/14).

Tumor classification:

ICDO-DA-M

8140/3

G3

pT3

L1, V1,

pN2 (6/14)

Source: NCI Genomic Data Commons file 3e331e6c-3f68-410f-89fa-4db0f9ef6555 (TCGA-AA-3952.9537881F-28E0-405F-8582-F3807185D4EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).